Somatic mutation profile of tumor specimen TCGA-UC-A7PG-01A (aliquot TCGA-UC-A7PG-01A-11D-A42O-09) from TCGA case TCGA-UC-A7PG, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G1; Age at diagnosis: 44.4 years (16,231 days).
Specimen TCGA-UC-A7PG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6d3bf5e-401d-4f64-b399-63ce6a5dc656.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UC-A7PG-11C (Solid Tissue Normal), aliquot TCGA-UC-A7PG-11C-11D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b712742-08eb-4375-979b-0c456bfd6ba9

The open-access MAF lists 293 somatic variants for this specimen: 216 protein-altering or splice-affecting, 63 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 191, Silent 63, Nonsense Mutation 19, Intron 5, RNA 5, Splice Region 4, 3'UTR 2, Translation Start Site 1, 3'Flank 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABHD6 | c.694C>G p.L232V | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV99916888; called by muse, mutect2, varscan2
- ACP3 | c.83G>T p.R28L | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV60485239; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4337G>A p.R1446H | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.019); catalogued as rs141060865; called by muse, mutect2, varscan2
- ADGRV1 | c.443C>T p.S148L | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV67985636; called by muse, mutect2
- ADPRM | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.627); catalogued as rs199523732; called by muse, varscan2
- AIFM1 | c.890C>T p.S297L | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.752); catalogued as COSV99780733; called by muse, mutect2, varscan2
- ALOX12B | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.201); catalogued as COSV100047688; called by muse, mutect2, varscan2
- ANK2 | c.11194G>C p.E3732Q | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.665); catalogued as COSV100004116; called by muse, mutect2, varscan2
- ANXA2 | c.455A>G p.K152R | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.12); catalogued as COSV100221868; called by muse, mutect2
- AP2A1 | c.890C>G p.S297C | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100756113; called by muse, mutect2, varscan2
- APBB2 | c.1851G>A p.M617I (on ENST00000295974 / NM_001166050.2; = p.M618I on NM_004307.2) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99924063; called by muse, mutect2, varscan2
- APOBR | c.1773G>C p.R591S (on ENST00000431282; = p.R600S on NM_018690.4) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.75); PolyPhen benign (0.167); catalogued as COSV100112925; called by muse, mutect2, varscan2
- AREL1 | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.115); catalogued as COSV100707555; called by muse, mutect2, varscan2
- ATP6V1A | c.1708A>G p.I570V | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.251); catalogued as COSV99849838; called by muse, mutect2, varscan2
- BCLAF3 | c.604C>T p.Q202* | Nonsense Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as COSV100503397; called by muse, mutect2, varscan2
- BRCA1 | c.5464C>A p.H1822N | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.523); catalogued as COSV100523268, COSV58793741; called by muse, mutect2, varscan2
- BRWD1 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100314043; called by muse, mutect2, varscan2
- CAMSAP2 | c.1830G>C p.L610F (on ENST00000236925 / NM_001297707.2; = p.L599F on NM_203459.3) | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.851); catalogued as COSV99374266; called by muse, mutect2, varscan2
- CAPN6 | c.727G>C p.E243Q | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.065); catalogued as COSV100137062; called by muse, mutect2
- CARD6 | c.1649C>A p.S550Y | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99621280; called by muse, mutect2, varscan2
- CAVIN4 | c.23C>G p.S8* | Nonsense Mutation (SNP) | VAF 8/51 reads (16%) | catalogued as COSV100293390; called by muse, mutect2, varscan2
- CCDC86 | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV99920301; called by muse, mutect2
- CD180 | c.1968G>C p.W656C | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV56520150, COSV99842077; called by muse, mutect2, varscan2
- CD226 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.121); catalogued as COSV99711496; called by muse, mutect2, varscan2
- CDC123 | c.953A>G p.D318G | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as COSV99826657; called by muse, mutect2, varscan2
- CDCP2 | c.1196C>G p.S399C | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as COSV100313673; called by muse, mutect2, varscan2
- CDH9 | c.2353G>A p.D785N | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as COSV99141346; called by muse, mutect2, varscan2
- CDHR3 | c.2622G>A p.M874I | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as COSV100488851; called by muse, mutect2, varscan2
- CEP350 | c.3298C>G p.P1100A | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as COSV100855207; called by muse, mutect2, varscan2
- CEP97 | c.191C>G p.S64* | Nonsense Mutation (SNP) | VAF 4/54 reads (7%) | catalogued as COSV59126849; called by muse, mutect2
- CERS1 | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1161008712, COSV99896784; called by muse, mutect2, varscan2
- CES1 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 38/444 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs369300055, COSV100828554; called by muse, mutect2
- CHD2 | c.2566G>C p.D856H | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV101245959; called by muse, mutect2
- CHRNA5 | c.1224G>A p.M408I | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV100213770; called by muse, mutect2, varscan2
- CLIP1 | c.3877C>T p.Q1293* (on ENST00000620786 / NM_001247997.1; = p.Q1282* on NM_002956.2) | Nonsense Mutation (SNP) | VAF 6/23 reads (26%) | catalogued as COSV100212340; called by muse, mutect2, varscan2
- CNTRL | c.6917C>G p.S2306C | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs965041473, COSV99441046; called by muse, mutect2, varscan2
- COL22A1 | c.4609C>T p.P1537S | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs933180755, COSV57342400; called by muse, mutect2
- COL4A6 | c.2908G>C p.D970H | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs1201284888, COSV100564997; called by muse, mutect2, varscan2
- CPXM1 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.44); catalogued as rs769164265, COSV66044985, COSV66045264, COSV66046515; called by muse, mutect2, varscan2
- CRACR2A | c.32G>C p.R11T | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.018); catalogued as COSV99365460; called by muse, mutect2
- CRAMP1 | c.3376G>C p.D1126H | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51964902; called by muse, mutect2
- CRLF1 | c.978C>G p.I326M | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100679041; called by muse, mutect2, varscan2
- CSF2RA | c.77-1G>C p.X26_splice | Splice Site (SNP) | VAF 23/199 reads (12%) | catalogued as COSV100817952, COSV62623655; called by muse, mutect2, varscan2
- CUL1 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57386998; called by muse, mutect2, varscan2
- DGCR2 | c.1361C>T p.S454F | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99593959; called by muse, mutect2, varscan2
- DIO3 | c.850G>C p.E284Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100832265; called by muse, mutect2, varscan2
- DLG3 | c.2038G>T p.E680* (on ENST00000374360 / NM_021120.4; = p.E375* on NM_020730.3) | Nonsense Mutation (SNP) | VAF 19/64 reads (30%) | catalogued as COSV52083092, COSV99530084; called by muse, mutect2, varscan2
- DMXL1 | c.2593G>C p.E865Q | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV100224928; called by muse, mutect2, varscan2
- DNAJC13 | c.2068C>T p.Q690* | Nonsense Mutation (SNP) | VAF 8/49 reads (16%) | catalogued as COSV99608075; called by muse, mutect2, varscan2
- DNMT1 | c.4312G>A p.D1438N | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV61578766; called by muse, mutect2, varscan2
- DOCK2 | c.778C>T p.R260* | Nonsense Mutation (SNP) | VAF 8/48 reads (17%) | catalogued as COSV56938995; called by muse, mutect2, varscan2
- EDN1 | c.351G>C p.K117N | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV101040477; called by muse, mutect2, varscan2
- EIF3L | c.1191G>C p.K397N | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.377); catalogued as COSV101094679; called by muse, mutect2
- EIF5 | c.1166C>T p.S389F | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99384824; called by muse, mutect2
- EPHA7 | c.495G>A p.M165I | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV100992524; called by muse, mutect2
- EPHA8 | c.2020A>T p.T674S | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV99384184; called by muse, mutect2, varscan2
- ERBB3 | c.2673G>C p.Q891H | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99917814; called by muse, mutect2, varscan2
- ETS1 | c.379G>T p.E127* | Nonsense Mutation (SNP) | VAF 15/71 reads (21%) | catalogued as COSV100090004; called by muse, mutect2, varscan2
- ETV1 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs1259444979, COSV99624476; called by muse, mutect2, varscan2
- EXO5 | c.379G>C p.E127Q | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.945); catalogued as COSV56415858, COSV99591198; called by muse, mutect2
- FAAH | c.954C>G p.V318= | Splice Region (SNP) | VAF 17/36 reads (47%) | catalogued as rs750300015, COSV99679864; called by muse, mutect2, varscan2
- FBLN2 | c.2225C>G p.S742C | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99852579; called by muse, mutect2, varscan2
- FBXO27 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as COSV99494753; called by muse, mutect2
- FHL1 | c.921G>A p.M307I (on ENST00000651089 / NM_001369326.1; = p.E241K on NM_001449.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as COSV100600852; called by muse, mutect2, varscan2
- FLG | c.4258C>A p.Q1420K | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.05); catalogued as COSV100910480; called by muse, mutect2
- FNDC11 | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs749067755, COSV100918840; called by muse, mutect2, varscan2
- FREM1 | c.34G>A p.V12M | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs199906654, COSV66527274; called by muse, varscan2
- FREM1 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs550846587, COSV101085431; called by muse, varscan2
- FST | c.836C>T p.S279L | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.178); catalogued as rs202174134, COSV56814987; called by muse, mutect2, varscan2
- GABRR1 | c.393G>C p.E131D | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.11); catalogued as COSV101034104; called by muse, mutect2
- GALNT11 | c.1663G>A p.G555R | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.125); catalogued as rs765599528, COSV57427334; called by muse, mutect2, varscan2
- GCH1 | c.544C>T p.Q182* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as CM077933, CM980891, COSV99582080; called by muse, mutect2
- GIMAP8 | c.920C>G p.S307* | Nonsense Mutation (SNP) | VAF 5/35 reads (14%) | catalogued as rs747459758, COSV100217699, COSV56229507, COSV56233783; called by muse, mutect2, varscan2
- GMEB1 | c.1690C>G p.H564D | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV99602909; called by muse, mutect2, varscan2
- GNAS | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as CD920862, COSV55673978; called by muse, mutect2, varscan2
- GPATCH3 | c.245C>T p.S82L | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100658914; called by muse, mutect2, varscan2
- GPR107 | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.732); catalogued as rs200754726, COSV61277037; called by muse, mutect2, varscan2
- GRK2 | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs1226475013, COSV100419750; called by muse, mutect2
- HIPK1 | c.1684C>G p.H562D | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.84); catalogued as COSV100479644; called by muse, mutect2, varscan2
- HLTF | c.3009C>G p.I1003M | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV56050253, COSV99936957; called by muse, mutect2, varscan2
- HS1BP3 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as rs569287360, COSV100397784; called by muse, mutect2, varscan2
- HSD3B1 | c.596C>G p.S199C | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.06); catalogued as COSV99347797; called by muse, mutect2, varscan2
- HTR6 | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.211); catalogued as rs760097478, COSV99229869; called by muse, mutect2, varscan2
- HYDIN | c.14761C>G p.L4921V | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as COSV101125078, COSV101125218; called by muse, mutect2, varscan2
- IGSF1 | c.3113G>T p.C1038F | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63841161; called by muse, mutect2, varscan2
- IL12RB2 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99255631; called by muse, mutect2, varscan2
- IQCG | c.1020G>A p.M340I | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.152); catalogued as COSV99502019; called by muse, mutect2, varscan2
- IRF1 | c.173G>T p.W58L | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99810376; called by muse, mutect2, varscan2
- KANK2 | c.2095C>T p.R699C (on ENST00000586659 / NM_001379562.1; = p.R707C on NM_015493.7 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs143339573, COSV100763037, COSV62007383; called by muse, mutect2, varscan2
- KCNE2 | c.173G>C p.G58A | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99285801; called by muse, mutect2, varscan2
- KERA | c.467G>A p.R156K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV57131040, COSV99899574; called by muse, varscan2
- KIRREL1 | c.1481C>A p.P494H | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100780102; called by muse, mutect2
- KLRC4 | c.326G>A p.R109K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV100511351; called by mutect2, varscan2
- KNDC1 | c.3735G>C p.Q1245H | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs757488436, COSV100466152; called by muse, mutect2, varscan2
- LAMA5 | c.10411G>A p.G3471S | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); catalogued as rs554068591, COSV99442163; called by muse, varscan2
- LIMK1 | c.1864G>C p.E622Q | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.65); catalogued as COSV100282991; called by muse, mutect2
- LRP1B | c.5989C>T p.Q1997* | Nonsense Mutation (SNP) | VAF 10/54 reads (19%) | catalogued as COSV101260589, COSV67266584; called by muse, mutect2, varscan2
- LRP4 | c.5605G>C p.E1869Q | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.34); catalogued as COSV101066865; called by muse, mutect2
- LRRC7 | c.4381C>T p.R1461W (on ENST00000651989 / NM_001370785.2; = p.R1381W on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs199872098, COSV99229614; called by muse, mutect2, varscan2
- MAP4K1 | c.435C>G p.I145M | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV101204401; called by muse, mutect2
- MAPK8IP3 | c.1745C>T p.S582F | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV99169698; called by muse, mutect2, varscan2
- MAST4 | c.4293G>C p.K1431N (on ENST00000403625 / NM_001164664.2; = p.K1242N on NM_015183.3) | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99845760; called by muse, mutect2
- MCF2 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as COSV100644421; called by muse, mutect2, varscan2
- MDH2 | c.502G>A p.G168S | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs782546937, COSV100242557; called by muse, mutect2, varscan2
- MDN1 | c.13898G>A p.R4633H | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs183262103; called by muse, mutect2, varscan2
- MEGF8 | c.5884G>A p.E1962K (on ENST00000251268 / NM_001271938.2; = p.E1895K on NM_001410.3) | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.154); catalogued as rs1454888198, COSV52079694; called by muse, mutect2, varscan2
- MEPCE | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52769066; called by muse, mutect2, varscan2
- MKI67 | c.6134C>G p.S2045C | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV100896967; called by muse, mutect2, varscan2
- MLF2 | c.67C>T p.H23Y | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV99180115; called by muse, mutect2
- MMD2 | c.288C>G p.L96= | Splice Region (SNP) | VAF 5/35 reads (14%) | catalogued as COSV101287136; called by muse, mutect2
- MORN4 | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100167440; called by muse, mutect2, varscan2
- MRM3 | c.265G>C p.E89Q | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.854); catalogued as COSV100022800, COSV100022827; called by muse, mutect2
- MROH7 | c.1770G>C p.L590F | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100274016; called by muse, mutect2, varscan2
- MSN | c.754G>C p.D252H | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100814300, COSV64305050; called by mutect2, varscan2
- MTF2 | c.447G>T p.W149C | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100940186; called by muse, mutect2
- MTMR4 | c.839G>C p.S280T | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.026); catalogued as COSV100050749; called by muse, mutect2, varscan2
- MYH8 | c.3799G>C p.E1267Q | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs1421931499, COSV101238761; called by muse, mutect2, varscan2
- NACA2 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as rs1388775574, COSV71713114, COSV71713117; called by muse, mutect2, varscan2
- NAXD | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs376240618; called by muse, varscan2
- NISCH | c.2423G>A p.R808H | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as COSV100617112; called by muse, mutect2, varscan2
- NLN | c.1826G>A p.G609E | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV101114468; called by muse, mutect2, varscan2
- NLRP8 | c.1448G>C p.G483A | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1220040611, COSV52594993, COSV99405924; called by muse, mutect2, varscan2
- NMT2 | c.182C>T p.S61F | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as COSV65382740; called by muse, mutect2, varscan2
- NRK | c.4741G>C p.D1581H | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.085); catalogued as COSV54606746, COSV99689108; called by muse, mutect2, varscan2
- NSD1 | c.7531G>T p.D2511Y | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.347); catalogued as COSV100728381, COSV100729780; called by muse, mutect2, varscan2
- NTN4 | c.1081G>A p.D361N | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100643868; called by muse, mutect2, varscan2
- OLFML2B | c.190G>T p.D64Y | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99668895; called by muse, mutect2, varscan2
- OR10J3 | c.32A>T p.E11V | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV100171876; called by muse, mutect2, varscan2
- OR2M3 | c.658C>G p.R220G | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.778); catalogued as rs375262830, COSV71758954; called by muse, mutect2, varscan2
- OR2V2 | c.834C>G p.F278L | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV100080236; called by muse, mutect2, varscan2
- OR3A2 | c.470C>G p.S157C | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.03); catalogued as COSV101375082, COSV68694971; called by muse, mutect2, varscan2
- OR51B4 | c.360C>G p.F120L | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100970557, COSV66517755; called by muse, mutect2, varscan2
- OR51E2 | c.72C>G p.F24L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.955); catalogued as COSV101211400, COSV67807769; called by muse, mutect2, varscan2
- P4HA1 | c.1080G>C p.L360= | Splice Region (SNP) | VAF 8/52 reads (15%) | catalogued as COSV99697211; called by muse, mutect2, varscan2
- PAAF1 | c.329C>G p.S110C | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV100142700; called by muse, mutect2, varscan2
- PADI2 | c.1177G>A p.V393M | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs765325408, COSV64946144; called by muse, mutect2
- PALM2AKAP2 | c.979C>T p.R327C (on ENST00000259318 / NM_001136562.3; = p.R558C on NM_007203.5) | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs376308694; called by muse, mutect2, varscan2
- PARP9 | c.1306G>C p.E436Q | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.072); catalogued as COSV100831256; called by muse, mutect2, varscan2
- PCCB | c.859C>G p.P287A | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.117); catalogued as COSV52443591; called by muse, mutect2, varscan2
- PCDH15 | c.2539G>A p.D847N | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751941551, CM165391, COSV57288231, COSV57352576; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHA7 | c.2117C>T p.A706V | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.057); catalogued as rs547705434, COSV65335606; called by muse, mutect2, varscan2
- PCYT1A | c.455C>T p.T152M | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as rs746655391, COSV99491923; called by muse, mutect2, varscan2
- PDE4B | c.1411G>T p.D471Y | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100302159; called by muse, mutect2, varscan2
- PEG3 | c.3205G>A p.D1069N | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV55628376, COSV55629402; called by muse, mutect2, varscan2
- PHLDB3 | c.1198G>C p.E400Q | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.305); catalogued as COSV99415981; called by muse, mutect2, varscan2
- PHRF1 | c.1380G>C p.K460N (on ENST00000264555 / NM_001286581.2; = p.K459N on NM_020901.4) | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99199454; called by muse, mutect2, varscan2
- PIBF1 | c.879G>A p.M293I | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100411932; called by muse, mutect2, varscan2
- PIGB | c.891G>C p.Q297H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.02); catalogued as COSV99380714; called by muse, mutect2, varscan2
- PITPNM1 | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.4); catalogued as COSV100711733; called by muse, mutect2, varscan2
- PKD1 | c.1621G>T p.A541S | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.328); catalogued as COSV99239005; called by muse, mutect2, varscan2
- PKD1L1 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1394070930, COSV99218346; called by muse, mutect2, varscan2
- PLCE1 | c.184G>T p.E62* | Nonsense Mutation (SNP) | VAF 11/25 reads (44%) | catalogued as COSV53347562, COSV99593434; called by muse, mutect2, varscan2
- PLK1 | c.789C>G p.I263M | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100267463; called by muse, mutect2, varscan2
- POLR2C | c.715C>G p.L239V | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV54673230, COSV99538462; called by muse, mutect2
- PPIE | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.215); catalogued as COSV100180202; called by muse, mutect2, varscan2
- PPP2R2A | c.1145C>T p.S382L | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV100277359; called by muse, mutect2, varscan2
- PPP4R1 | c.983C>T p.S328L (on ENST00000400556 / NM_001042388.3; = p.S311L on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.496); catalogued as COSV99553953; called by muse, mutect2, varscan2
- PTPRU | c.3367C>T p.R1123W | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867290552, COSV60534846; called by muse, mutect2, varscan2
- PYHIN1 | c.920G>C p.R307T | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); catalogued as COSV100932361, COSV100932412; called by muse, mutect2, varscan2
- RARB | c.1027G>A p.E343K (on ENST00000383772 / NM_001290216.2; = p.E336K on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.963); catalogued as COSV51970894, COSV99979096; called by muse, mutect2, varscan2
- RERE | c.2183C>T p.S728L | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100557275; called by muse, mutect2, varscan2
- RERE | c.1043C>T p.S348F | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV100557277; called by muse, mutect2
- RFX7 | c.709G>A p.E237K (on ENST00000559447 / NM_001368074.1; = p.E334K on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.214); catalogued as rs1217945309, COSV100429366; called by muse, mutect2, varscan2
- RFXAP | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated, low confidence (0.26); PolyPhen probably damaging (0.932); catalogued as rs1172888518, COSV99715111; called by muse, mutect2
- RIMS1 | c.869G>A p.R290Q | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs1479837493, COSV99325862; called by muse, mutect2
- RND3 | c.272C>G p.S91C | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.998); catalogued as COSV99812179; called by muse, varscan2
- SAXO2 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV100255555; called by muse, mutect2, varscan2
- SCN9A | c.5102A>C p.D1701A (on ENST00000303354; = p.D1690A on NM_002977.3) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); catalogued as COSV100314150; called by muse, mutect2, varscan2
- SGO1 | c.1063G>A p.D355N | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.796); catalogued as COSV99768473; called by muse, mutect2, varscan2
- SIPA1L3 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as rs771614621, COSV55911872; called by muse, varscan2
- SLC44A2 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1355261894, COSV59836055, COSV59838669; called by muse, mutect2, varscan2
- SLC5A1 | c.1166C>G p.S389C | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99833735; called by muse, mutect2, varscan2
- SLC6A16 | c.1872C>G p.I624M | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.786); catalogued as COSV100242938; called by muse, mutect2, varscan2
- SPATA31D1 | c.3913G>A p.D1305N | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV100783045, COSV61201483; called by muse, mutect2, varscan2
- SPRED1 | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV100136411; called by muse, mutect2, varscan2
- SPRED2 | c.1116G>C p.E372D | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.783); catalogued as COSV100710341; called by muse, mutect2, varscan2
- SRFBP1 | c.1025C>G p.S342* | Nonsense Mutation (SNP) | VAF 7/24 reads (29%) | catalogued as COSV100232975; called by muse, mutect2, varscan2
- STAC2 | c.799G>C p.E267Q | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as COSV100336482; called by muse, mutect2, varscan2
- SUN2 | c.1180G>C p.E394Q | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.03); catalogued as COSV99325826; called by muse, mutect2, varscan2
- SUN3 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.039); catalogued as rs1229088173, COSV99813805; called by muse, mutect2, varscan2
- SUPT16H | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.111); catalogued as COSV53522874; called by muse, mutect2, varscan2
- SYNE2 | c.10471G>A p.E3491K | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.638); catalogued as COSV100646642; called by muse, mutect2, varscan2
- TDRD6 | c.2410G>A p.D804N | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.014); catalogued as COSV60178016; called by muse, mutect2, varscan2
- TDRD7 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.865); catalogued as COSV62431511; called by muse, mutect2, varscan2
- THAP12 | c.1609G>C p.E537Q | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); catalogued as COSV99473244; called by muse, mutect2, varscan2
- TIAM1 | c.3539C>T p.S1180F | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); catalogued as COSV99732493, COSV99732686, COSV99736194; called by muse, mutect2, varscan2
- TNS2 | c.206G>A p.R69K (on ENST00000314250 / NM_170754.4; = p.R79K on NM_015319.2) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.95); PolyPhen benign (0.012); catalogued as COSV100047405; called by muse, mutect2, varscan2
- TPX2 | c.1843G>A p.E615K | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as COSV55917886; called by muse, mutect2, varscan2
- TRAPPC13 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.059); catalogued as COSV99198980; called by muse, mutect2, varscan2
- TREM1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99776301; called by muse, mutect2
- TTK | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773610148, COSV57881289, COSV57883755; called by muse, mutect2, varscan2
- TUSC3 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.72); PolyPhen benign (0.034); catalogued as COSV101140356; called by muse, mutect2, varscan2
- UNC13D | c.787C>A p.L263M | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99255986; called by muse, mutect2, varscan2
- UROS | c.241G>C p.E81Q | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.069); catalogued as COSV100908908; called by muse, mutect2, varscan2
- USP30 | c.335C>G p.S112* | Nonsense Mutation (SNP) | VAF 7/43 reads (16%) | catalogued as COSV99980605; called by muse, mutect2, varscan2
- VPS41 | c.2556G>A p.M852I | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV100054325; called by muse, mutect2, varscan2
- WSCD1 | c.504G>C p.K168N | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV100496370; called by muse, mutect2, varscan2
- XK | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781856258, COSV66120998; called by muse, mutect2, varscan2
- ZC3H4 | c.1800G>C p.V600= | Splice Region (SNP) | VAF 5/69 reads (7%) | catalogued as COSV99452773; called by muse, mutect2
- ZFHX4 | c.2907G>T p.Q969H | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99267301; called by muse, mutect2, varscan2
- ZIM2 | c.520G>T p.E174* | Nonsense Mutation (SNP) | VAF 9/43 reads (21%) | catalogued as COSV99687177; called by muse, mutect2, varscan2
- ZNF16 | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | catalogued as COSV99429885; called by muse, mutect2, varscan2
- ZNF280B | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.173); catalogued as COSV100840439, COSV64528435; called by muse, mutect2, varscan2
- ZNF366 | c.663G>C p.E221D | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV100574061; called by muse, mutect2, varscan2
- ZNF446 | c.625C>T p.Q209* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as COSV99543484; called by muse, mutect2
- ZNF573 | c.1562C>T p.T521I (on ENST00000536220 / NM_001172692.1; = p.T463I on NM_152360.3) | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV100265835; called by muse, mutect2
- ZNF587 | c.616C>T p.Q206* | Nonsense Mutation (SNP) | VAF 14/105 reads (13%) | catalogued as rs757542589, COSV100299664; called by muse, mutect2, varscan2
- ZNF675 | c.1058C>G p.S353* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | catalogued as COSV100704888; called by muse, mutect2, varscan2
- ZNF768 | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as rs1176774306, COSV63320979; called by mutect2, varscan2
- ZNF831 | c.361C>A p.L121M | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100926246, COSV64043567; called by muse, mutect2
- C16orf82 | c.202G>C p.E68Q | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- CMYA5 | c.2156C>T p.S719F | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.017); called by mutect2, varscan2
- IGHA1 | c.1042G>A p.V348M | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.617); called by muse, mutect2
- MISP | c.1714G>A p.E572K | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.053); called by muse, mutect2
- NBPF11 | c.1951G>C p.D651H | Missense Mutation (SNP) | VAF 25/304 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); called by muse, mutect2
- SIN3A | c.1769C>T p.S590L | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); called by muse, mutect2
- AADAC | c.237C>T p.V79= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as COSV99233065; called by muse, mutect2, varscan2
- AC092143.1 | c.1851C>T p.F617= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as rs551650733, COSV59248160; called by muse, mutect2, varscan2
- AGAP6 | c.1254G>A p.Q418= (on ENST00000374056 / NM_001365867.1; = p.Q441= on NM_001077665.2) | Silent (SNP) | VAF 21/131 reads (16%) | catalogued as rs1382570624, COSV100929152; called by muse, mutect2, varscan2
- ANXA1 | c.126C>T p.F42= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs755464124, COSV99974082; called by muse, mutect2, varscan2
- AOPEP | c.2382C>G p.L794= (on ENST00000375315 / NM_001193329.1; = p.L695= on NM_032823.5) | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV99950799; called by muse, mutect2, varscan2
- C16orf71 | c.324G>A p.Q108= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as COSV54794890; called by muse, mutect2, varscan2
- C9orf78 | c.592C>T p.L198= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV100989991; called by muse, mutect2, varscan2
- CA9 | c.1365C>T p.A455= | Silent (SNP) | VAF 22/95 reads (23%) | catalogued as rs763328908, COSV100253506; called by muse, mutect2, varscan2
- CCDC141 | c.1944C>T p.L648= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV55369510; called by muse, mutect2, varscan2
- CCDC3 | c.93G>A p.L31= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV101121753; called by muse, mutect2
- CDH20 | c.2166C>G p.V722= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV99404261; called by muse, mutect2, varscan2
- CFAP61 | c.3708C>T p.I1236= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs148140719; called by muse, varscan2
- CTSE | c.12C>G p.L4= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as COSV100733750; called by muse, mutect2, varscan2
- CYP2A13 | c.678G>A p.V226= | Silent (SNP) | VAF 13/107 reads (12%) | catalogued as COSV100387004; called by muse, mutect2, varscan2
- DCLK2 | c.975C>A p.P325= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV99652720; called by muse, mutect2, varscan2
- DIP2B | c.4407G>C p.L1469= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV99999329; called by muse, mutect2, varscan2
- ERBB3 | c.3093C>T p.L1031= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV99915700; called by muse, mutect2, varscan2
- ERBB3 | c.3546C>A p.L1182= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV99915702; called by muse, mutect2, varscan2
- FZD1 | c.1943G>A p.*648= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV99842739; called by muse, mutect2, varscan2
- GALNT12 | c.1020C>G p.L340= | Silent (SNP) | VAF 5/54 reads (9%) | catalogued as COSV100899189, COSV66662465; called by mutect2, varscan2
- GAN | c.492C>T p.V164= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as rs553692036, COSV101634029; ClinVar: likely benign; called by muse, mutect2, varscan2
- GLB1L2 | c.435C>T p.L145= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as rs751127248, COSV60280636; called by muse, mutect2, varscan2
- HEG1 | c.1338C>T p.V446= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs771255321, COSV60763007; called by muse, mutect2, varscan2
- INPPL1 | c.1431C>T p.G477= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs374378161; called by muse, varscan2
- ITIH5 | c.2427C>T p.L809= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as rs372080524, COSV99905685; called by muse, mutect2, varscan2
- KCNA3 | c.1242C>T p.S414= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV63901463; called by muse, mutect2, varscan2
- KLHL28 | c.822G>A p.L274= | Silent (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- KRT2 | c.1734C>T p.G578= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV100548643; called by muse, mutect2, varscan2
- KRT86 | c.975G>C p.L325= | Silent (SNP) | VAF 6/87 reads (7%) | called by muse, mutect2
- MAGI3 | c.1761G>C p.G587= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV100290374; called by muse, mutect2, varscan2
- MAN2A1 | c.54G>C p.V18= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV99811866; called by muse, mutect2, varscan2
- MGAM | c.762C>G p.L254= | Silent (SNP) | VAF 11/81 reads (14%) | catalogued as COSV101516547; called by muse, mutect2, varscan2
- MMP21 | c.1149C>G p.L383= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as COSV100916660; called by muse, mutect2, varscan2
- MUC16 | c.9735C>G p.V3245= | Silent (SNP) | VAF 4/64 reads (6%) | called by muse, mutect2
- MYO9B | c.2796G>A p.Q932= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV101261242; called by muse, mutect2, varscan2
- NUP188 | c.2481G>A p.L827= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV101001489; called by muse, mutect2, varscan2
- OBSCN | c.14106C>A p.I4702= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV99484038; called by muse, mutect2
- PCDHA11 | c.2187C>T p.G729= | Silent (SNP) | VAF 19/36 reads (53%) | catalogued as COSV56484702; called by muse, mutect2, varscan2
- PCNX1 | c.108C>G p.L36= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV53096010; called by muse, mutect2, varscan2
- PEX11B | c.681C>T p.L227= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV100995037; called by muse, mutect2, varscan2
- PLEKHG5 | c.960C>T p.F320= (on ENST00000400915 / NM_001042663.3; = p.F283= on NM_020631.6) | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs750570012, COSV61701617; called by muse, mutect2
- PLXNA3 | c.4260C>T p.F1420= | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as rs782274788, COSV100860232; called by muse, mutect2, varscan2
- PTCHD4 | c.717G>A p.V239= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs372931604; called by mutect2, varscan2
- RAD23A | c.528G>A p.E176= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as COSV100331077; called by muse, mutect2
- RAPGEF1 | c.3048C>T p.F1016= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as COSV100940746; called by muse, mutect2, varscan2
- RTEL1 | c.2964G>A p.Q988= | Silent (SNP) | VAF 4/58 reads (7%) | catalogued as rs1380817783, COSV100541534; called by muse, mutect2
- SGSH | c.255G>A p.Q85= | Silent (SNP) | VAF 25/74 reads (34%) | catalogued as COSV100413312; called by muse, mutect2, varscan2
- SIGLEC10 | c.783C>G p.V261= | Silent (SNP) | VAF 7/86 reads (8%) | catalogued as COSV100219430; called by muse, mutect2
- SLC25A43 | c.771G>A p.V257= | Silent (SNP) | VAF 5/74 reads (7%) | catalogued as COSV99474396; called by muse, mutect2
- SLC5A11 | c.1380G>A p.P460= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs774164600, COSV61741697; called by muse, varscan2
- SLCO3A1 | c.483C>T p.P161= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs755280875, COSV100574888; called by mutect2, varscan2
- SNX14 | c.162C>A p.I54= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV100121763, COSV59011800; called by muse, mutect2, varscan2
- SPAM1 | c.1200C>T p.L400= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as COSV99772678; called by muse, mutect2, varscan2
- SPG11 | c.2661C>T p.L887= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV99969578; called by muse, mutect2, varscan2
- SURF4 | c.645C>T p.I215= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as rs143463762; called by muse, mutect2, varscan2
- TBC1D4 | c.3405G>A p.E1135= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs540075377, COSV100884518; called by muse, mutect2, varscan2
- TEP1 | c.4326G>A p.P1442= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs751812867, COSV52994803; called by muse, mutect2, varscan2
- TMEM182 | c.288C>T p.F96= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs1314464949, COSV101305328, COSV101305364; called by muse, mutect2, varscan2
- TTC13 | c.1038C>T p.L346= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV100793023; called by muse, mutect2, varscan2
- VIRMA | c.4044C>T p.V1348= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs1377464942, COSV52587336; called by muse, mutect2, varscan2
- XIRP2 | c.351G>C p.L117= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV99747116; called by muse, mutect2, varscan2
- ZDHHC11 | c.939C>G p.V313= | Silent (SNP) | VAF 5/90 reads (6%) | catalogued as COSV99363560; called by muse, mutect2
- ZW10 | c.486C>T p.L162= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV99562424; called by muse, mutect2, varscan2
- AC244258.1 | n.903G>T | RNA (SNP) | VAF 12/44 reads (27%) | called by muse, mutect2, varscan2
- DCHS2 | n.4787G>A | RNA (SNP) | VAF 14/49 reads (29%) | catalogued as rs142512414; called by muse, mutect2, varscan2
- DUOXA1 | chr15:45117523 G>A | 3'Flank (SNP) | VAF 5/44 reads (11%) | catalogued as rs1190702126, COSV99973534; called by muse, mutect2, varscan2
- FRMPD2B | n.1219G>A | RNA (SNP) | VAF 8/51 reads (16%) | called by mutect2, varscan2
- HERC2P3 | n.372G>A | RNA (SNP) | VAF 18/362 reads (5%) | catalogued as rs1200610298; called by muse, mutect2
- HNRNPK | c.1361+356G>A | Intron (SNP) | VAF 4/30 reads (13%) | catalogued as COSV100698865; called by muse, mutect2, varscan2
- L1CAM | chrX:153886979 G>C | 5'Flank (SNP) | VAF 23/125 reads (18%) | called by muse, mutect2, varscan2
- LEKR1 | c.*1186G>A | 3'UTR (SNP) | VAF 6/60 reads (10%) | catalogued as COSV100738565; called by muse, mutect2
- LMNA | c.357-3706C>G | Intron (SNP) | VAF 13/90 reads (14%) | catalogued as COSV100738835; called by muse, mutect2, varscan2
- NOP56 | c.569+167G>C | Intron (SNP) | VAF 9/64 reads (14%) | catalogued as COSV100250298, COSV100250330; called by muse, varscan2
- NT5C1B-RDH14 | c.*157C>G | 3'UTR (SNP) | VAF 4/35 reads (11%) | catalogued as COSV101173280; called by muse, mutect2
- POLA1 | c.2947-21186C>T | Intron (SNP) | VAF 13/91 reads (14%) | called by muse, mutect2, varscan2
- PTK2 | c.2030+2657C>G | Intron (SNP) | VAF 5/39 reads (13%) | catalogued as COSV100571180; called by muse, mutect2, varscan2
- SSPOP | n.15704G>A | RNA (SNP) | VAF 14/113 reads (12%) | catalogued as rs373429712; called by muse, mutect2, varscan2
